Gene-level copy-number profile of tumor specimen TCGA-13-0913-02A from TCGA case TCGA-13-0913, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.6 years (19,573 days).
Specimen TCGA-13-0913-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a03cdd75-db90-4a09-9eb4-23f2b95b0790.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0913-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate.
https://portal.gdc.cancer.gov/files/01c31f9c-08df-4284-859d-c3396b327176

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 918; copy number 1: 18,283; copy number 2: 35,127; copy number 3: 4,802; copy number 4: 637; copy number 5: 196; copy number 6: 293; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 397 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–147,056,593, 112 genes (within-gene range 0–2) (broad region; genes not listed).
- chr2:241,227,264–241,317,061, 1 gene (within-gene range 0–2): HDLBP.
- chr8:150,584–10,712,187, 257 genes (within-gene range 0–1) (broad region; genes not listed).
- chr10:88,879,734–89,420,997, 19 genes: STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5.
- chr10:89,456,064–89,468,140, 1 gene (within-gene range 0–1): SLC16A12-AS1.
- chr16:85,899,162–85,922,606, 1 gene (within-gene range 0–1): IRF8.
- chr19:20,340,269–20,424,969, 1 gene (within-gene range 0–2): ZNF826P.
- chr19:20,389,658–20,571,095, 5 genes (within-gene range 0–2): AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 491 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:123,497,889–144,683,464, 384 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:86,945,679–87,330,052, 9 genes, copy number 5: FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1.
- chr11:93,052,395–97,086,682, 98 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,538. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
